Somatic mutation profile of tumor specimen MMRF_2257_1_BM_CD138pos (aliquot MMRF_2257_1_BM_CD138pos_T1_KHS5U_L11040) from MMRF case MMRF_2257, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,755 days).
Specimen MMRF_2257_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42e9af3c-c0da-4813-b844-3b2f020bd181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2257_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2257_1_PB_WBC_C2_KHS5U_L11039; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b0015a6-da3e-406a-9705-7a7e64cc1a27

The open-access MAF lists 64 somatic variants for this specimen: 26 protein-altering or splice-affecting, 1 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 18, 5'Flank 6, Intron 5, 5'UTR 5, 3'Flank 2, Frame Shift Del 1, Splice Site 1, RNA 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB10 | c.1115G>A p.R372H (on ENST00000420175 / NM_001142459.2; = p.R357H on NM_080871.4) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.925); catalogued as rs912069244; called by muse, mutect2
- CNIH3 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs775410636, COSV55272980, COSV55273623; called by muse, mutect2, varscan2
- DNAH17 | c.4738C>T p.R1580W | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749988595; called by muse, mutect2, varscan2
- DOCK4 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs373281415; called by muse, mutect2, varscan2
- IGKC | c.70_71del p.S24Cfs*7 | Frame Shift Del (DEL) | VAF 25/122 reads (20%) | catalogued as rs1217301377; called by pindel, varscan2
- IGLV4-60 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 36/208 reads (17%) | catalogued as rs754864365; called by muse, mutect2, varscan2
- KLF2 | c.824G>C p.S275T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV50179841, COSV99934120; called by muse, mutect2, varscan2
- MUC5B | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs759975789; called by muse, mutect2, varscan2
- MYH6 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62451850; called by muse, mutect2
- NLGN1 | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1224750292; called by muse, mutect2, varscan2
- PAQR9 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1427238410; called by muse, mutect2, varscan2
- PLK1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs200843318, COSV55624337; called by mutect2, varscan2
- RAB39A | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs770139140; called by muse, mutect2, varscan2
- ACP4 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APBB2 | c.1252-2A>G p.X418_splice (on ENST00000295974 / NM_001166050.2; = p.X419_splice on NM_004307.2) | Splice Site (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF7 | c.920T>C p.L307S (on ENST00000375741 / NM_001113511.2; = p.L129S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMPR2 | c.2209G>C p.V737L | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GABRA4 | c.1066T>A p.S356T | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2
- IGHV2-70D | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- LRRK1 | c.3619A>G p.R1207G | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- MTX2 | c.769C>A p.R257S | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR4K14 | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- PEX3 | c.65T>A p.V22D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PPP3R2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- SLC6A15 | c.1219T>G p.Y407D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TAP2 | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIX5 | c.417G>A p.E139= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52176430; called by muse, mutect2, varscan2
- ABI3 | chr17:49210425 C>T | 5'Flank (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- BCL7A | c.-2C>A | 5'UTR (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2
- BCL7A | c.-1C>T | 5'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2
- C9orf57 | c.*709C>G | 3'UTR (SNP) | VAF 5/95 reads (5%) | called by muse, mutect2
- CASKIN1 | c.*1276C>G | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- CFAP74 | c.500+11G>A | Intron (SNP) | VAF 31/171 reads (18%) | catalogued as rs1460227482; called by muse, mutect2, varscan2
- CNBP | c.*426A>G | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- CYP2B7P | n.327C>G | RNA (SNP) | VAF 23/176 reads (13%) | catalogued as rs753398839; called by muse, mutect2, varscan2
- EGF | c.-397C>A | 5'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, varscan2
- ELAVL4 | chr1:50106270 G>A | 5'Flank (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
- ELN | chr7:74069806 C>T | 3'Flank (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- ELOVL7 | c.*206_*209del | 3'UTR (DEL) | VAF 12/84 reads (14%) | catalogued as rs1402330755; called by mutect2, pindel, varscan2
- FGR | c.-13-98A>T | Intron (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- GDAP2 | c.*476T>C | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- GPR3 | c.*363_*364del | 3'UTR (DEL) | VAF 18/167 reads (11%) | catalogued as rs1428437384; called by pindel, varscan2
- H2AW | c.-5C>A | 5'UTR (SNP) | VAF 50/333 reads (15%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*1276G>A | 3'UTR (SNP) | VAF 13/102 reads (13%) | catalogued as rs568255866; called by muse, mutect2, varscan2
- KCNA4 | c.*751T>G | 3'UTR (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- LAD1 | chr1:201399429 G>A | 5'Flank (SNP) | VAF 12/112 reads (11%) | catalogued as rs775677192; called by muse, mutect2, varscan2
- LMBRD2 | c.*1405T>A | 3'UTR (SNP) | VAF 8/47 reads (17%) | catalogued as rs1209771818; called by muse, mutect2, varscan2
- MIA2 | chr14:39233921 del AG | 5'Flank (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- MIR5195 | chr14:106851372 T>C | 5'Flank (SNP) | VAF 35/155 reads (23%) | catalogued as rs1210231896; called by muse, mutect2, varscan2
- NCAPD3 | c.2783-435A>G | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- PGR | c.*2611T>C | 3'UTR (SNP) | VAF 16/96 reads (17%) | catalogued as COSV54800970; called by muse, mutect2, varscan2
- PHTF2 | c.*1531A>G | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- PLOD1 | c.580-187A>T | Intron (SNP) | VAF 53/271 reads (20%) | called by muse, mutect2, varscan2
- PSME3IP1 | c.*83A>T | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2
- RHEX | c.112+58T>G | Intron (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- RPL27A | c.*3777G>A | 3'UTR (SNP) | VAF 25/255 reads (10%) | called by muse, mutect2, varscan2
- SCYL2 | c.*1043C>T | 3'UTR (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- STXBP4 | c.*2210A>G | 3'UTR (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975616 C>A | 5'Flank (SNP) | VAF 42/106 reads (40%) | catalogued as COSV66082159; called by muse, mutect2, varscan2
- XPNPEP3 | c.*144T>C | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.-456G>A | 5'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as rs771408995; called by muse, mutect2, varscan2
- ZMIZ1 | c.*218C>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ZNF566 | chr19:36447374 G>A | 3'Flank (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- ZNF655 | c.*2261_*2262del | 3'UTR (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
